Gene-level copy-number profile of tumor specimen HCM-CSHL-0062-C18-01A from HCMI case HCM-CSHL-0062-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.6 years (25,784 days).
Specimen HCM-CSHL-0062-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82a6fc32-e977-4b7e-a09f-626cc0d68c58.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0062-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/2b247092-c190-4b01-a23e-84f70ce40c1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3; copy number 2: 52,625; copy number 3: 48; copy number 4: 5,723.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:174,724,582–174,730,896, 1 gene: MSX2.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr7:72,103,181–72,104,209, 1 gene (within-gene range 0–2): ABCF2P2.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–4): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
